Somatic mutation profile of tumor specimen TARGET-10-PAPANB-09A (aliquot TARGET-10-PAPANB-09A-01D) from TARGET case TARGET-10-PAPANB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,173 days).
Specimen TARGET-10-PAPANB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ceb44c5-b27e-41ee-a14e-7777ddd8035c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPANB-14A (Bone Marrow Normal), aliquot TARGET-10-PAPANB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cd88f83-214a-47dd-8151-ea0a82907484

The open-access MAF lists 32 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 9, Intron 4, 3'UTR 2, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNT18 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs376689514; called by muse, mutect2
- GREB1L | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 40/176 reads (23%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.987); catalogued as COSV52566313; called by muse, mutect2, varscan2
- GSN | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1246783224; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- LIFR | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756414449, COSV54700169; called by muse, mutect2, varscan2
- PLCB3 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs778033643; called by muse, mutect2, varscan2
- SCN3A | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51825823; called by muse, mutect2, varscan2
- SLC34A2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65941730; called by muse, mutect2, varscan2
- THNSL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs964320373, COSV59084671; called by muse, mutect2, varscan2
- TRDN | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs772876323; called by muse, mutect2, varscan2
- AEBP2 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CREBBP | c.4460A>T p.H1487L | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIK2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO18B | c.3958C>T p.L1320F | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POLR3C | c.297_305del p.S100_T102del | In Frame Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP36 | c.1074C>T p.C358= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- CLRN1 | c.48C>T p.F16= | Silent (SNP) | VAF 35/93 reads (38%) | called by muse, mutect2, varscan2
- CNGA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs141471697, COSV61704820; called by muse, mutect2, varscan2
- COL4A2 | c.2397C>T p.P799= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs890625154; called by muse, mutect2, varscan2
- CYP3A7 | c.1350G>A p.V450= | Silent (SNP) | VAF 42/80 reads (53%) | called by muse, mutect2, varscan2
- FASN | c.1590C>T p.F530= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs373355785; called by muse, mutect2, varscan2
- FSHR | c.2004G>A p.R668= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV58633859; called by muse, mutect2, varscan2
- OR51V1 | c.411C>T p.S137= | Silent (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- SOGA3 | c.2286C>T p.S762= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs757258840, COSV64107043; called by muse, mutect2, varscan2
- AL355390.1 | n.565C>T | RNA (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- CA14 | c.76+178C>T | Intron (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- CDK20 | c.*385C>T | 3'UTR (SNP) | VAF 40/151 reads (26%) | called by muse, mutect2, varscan2
- COL28A1 | c.883-594C>T | Intron (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- DLGAP2 | c.2704+17C>T | Intron (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- MSRB2 | c.*62C>T | 3'UTR (SNP) | VAF 32/169 reads (19%) | called by muse, mutect2, varscan2
- PENK | c.138+86G>A | Intron (SNP) | VAF 12/24 reads (50%) | catalogued as rs751969004, COSV100152544; called by muse, mutect2
